Somatic mutation profile of tumor specimen ALCH-AF00-TTP1-A (aliquot ALCH-AF00-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AF00, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.4 years (20,963 days).
Specimen ALCH-AF00-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 198dc6ba-0521-4733-8f71-6ffbef256e12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF00-NB1-A (Blood Derived Normal), aliquot ALCH-AF00-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57369c87-5685-461b-8592-0f634441e46e

The open-access MAF lists 81 somatic variants for this specimen: 57 protein-altering or splice-affecting, 18 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 18, Splice Site 4, Nonsense Mutation 3, 5'UTR 2, 3'UTR 2, Intron 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 164/809 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99976443, COSV99976928; called by muse, mutect2
- ATP13A3 | c.2081A>G p.E694G | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1013783455; called by muse, mutect2
- CCND2 | c.673T>A p.C225S | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99714278; called by muse, mutect2
- CYP7B1 | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs766368787; called by muse, mutect2
- DSG4 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs142245695; called by muse, mutect2, varscan2
- ERH | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV99220443; called by muse, mutect2
- FAM71A | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 31/530 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54234471; called by muse, mutect2
- FLG2 | c.690C>G p.N230K | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1423391420; called by muse, mutect2
- FOXP1 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as rs541340602, COSV59545555; called by muse, mutect2
- HSPB8 | c.367+1G>T p.X123_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as rs1565927116; called by muse, mutect2, varscan2
- IGFN1 | c.2426G>A p.R809Q (on ENST00000295591 / NM_001367841.1; = p.R3266Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.312); catalogued as rs762635850; called by muse, mutect2, varscan2
- MPL | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99055422; called by muse, mutect2
- OAS3 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 45/493 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766861655, COSV99966239; called by muse, mutect2
- PKHD1L1 | c.5674G>A p.V1892I | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV101005961, COSV65743648; called by muse, mutect2
- PTPRT | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100628368; called by muse, mutect2, varscan2
- SLC12A5 | c.409G>A p.V137I (on ENST00000454036 / NM_001134771.2; = p.V114I on NM_020708.5) | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as rs760750912, COSV54790791; ClinVar: uncertain significance; called by muse, mutect2
- SLC8A3 | c.665C>A p.A222E | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63519683; called by muse, mutect2
- TBC1D31 | c.2335C>T p.R779C | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs74653260; called by muse, mutect2, varscan2
- TRPV5 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 47/206 reads (23%) | catalogued as COSV54683238; called by muse, mutect2, varscan2
- ABCE1 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ACIN1 | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 20/367 reads (5%) | called by muse, mutect2
- ADAMTS18 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- AHCTF1 | c.4249G>A p.D1417N (on ENST00000366508; = p.D1391N on NM_015446.5) | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2
- ANKRD30BL | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- AQP8 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2
- ARMCX5-GPRASP2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CACNG3 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- CCDC110 | c.1782G>T p.Q594H | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL11A2 | c.2206G>T p.G736C (on ENST00000341947 / NM_080680.3; = p.G629C on NM_080679.2) | Missense Mutation (SNP) | VAF 46/704 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL4A6 | c.4271C>A p.P1424Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CUX1 | c.3472C>T p.Q1158* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.1735A>T p.N579Y | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAM186A | c.1697A>C p.K566T | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- FBXL14 | c.409C>G p.R137G | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.134); called by muse, mutect2
- FUBP3 | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPRIN3 | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 27/489 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); called by muse, mutect2
- HSPB8 | c.367+2T>C p.X123_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- IZUMO2 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.332); called by muse, mutect2
- KIF13A | c.3380T>G p.V1127G | Missense Mutation (SNP) | VAF 71/321 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP1 | c.2416A>G p.K806E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2
- MADD | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- MCCC2 | c.903+3G>C | Splice Region (SNP) | VAF 16/524 reads (3%) | called by muse, mutect2
- MFSD4A | c.1149+1G>T p.X383_splice | Splice Site (SNP) | VAF 34/560 reads (6%) | called by muse, mutect2
- NLGN4X | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.023); called by muse, mutect2
- OTOGL | c.4555G>T p.V1519F (on ENST00000547103; = p.V1510F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2
- PATL1 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCDH11Y | c.3208G>T p.A1070S | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- POLR3H | c.481T>A p.S161T | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.01); called by muse, mutect2
- PTBP3 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 26/428 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2
- RCSD1 | c.621G>C p.L207F | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPRED1 | c.207+1G>T p.X69_splice | Splice Site (SNP) | VAF 85/445 reads (19%) | called by muse, mutect2, varscan2
- TAX1BP1 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 36/715 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- TENM1 | c.6481A>G p.T2161A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TEX15 | c.2828G>C p.R943T (on ENST00000256246; = p.R1326T on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2
- ZNF646 | c.2413T>C p.S805P | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ZNF718 | c.605_629del p.E202Gfs*229 | Frame Shift Del (DEL) | VAF 13/137 reads (9%) | called by mutect2, pindel
- ACKR1 | c.255A>G p.R85= | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- ADGRL1 | c.2577G>A p.L859= (on ENST00000340736 / NM_001008701.3; = p.L854= on NM_014921.5) | Silent (SNP) | VAF 48/342 reads (14%) | catalogued as rs1422895565; called by muse, mutect2, varscan2
- CDC14C | c.1590G>A p.V530= (on ENST00000428251; = p.V423= on NM_152627.3) | Silent (SNP) | VAF 109/608 reads (18%) | called by muse, mutect2, varscan2
- CDC42EP5 | c.213G>T p.P71= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs749379600, COSV56618066; called by muse, mutect2, varscan2
- CLRN2 | c.378C>T p.V126= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs372352642; called by muse, mutect2, varscan2
- CNTD1 | c.774A>G p.G258= | Silent (SNP) | VAF 19/288 reads (7%) | called by muse, mutect2
- COL6A3 | c.5067C>T p.D1689= | Silent (SNP) | VAF 50/628 reads (8%) | catalogued as rs370475865, COSV55110246; called by muse, mutect2
- GABBR1 | c.405C>T p.F135= | Silent (SNP) | VAF 15/274 reads (5%) | called by muse, mutect2
- GUCY2F | c.2961G>T p.P987= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs761664456; called by muse, mutect2, varscan2
- IRX3 | c.837C>T p.D279= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- LAMC3 | c.4548G>A p.R1516= | Silent (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- NCEH1 | c.279A>C p.A93= (on ENST00000538775; = p.A61= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/305 reads (12%) | catalogued as COSV56433421; called by muse, mutect2, varscan2
- NOD1 | c.1140C>G p.A380= | Silent (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- OTOF | c.3915G>A p.K1305= (on ENST00000272371 / NM_194248.3; = p.K538= on NM_004802.4) | Silent (SNP) | VAF 61/570 reads (11%) | catalogued as COSV104379173; called by muse, varscan2
- PASD1 | c.1590G>A p.K530= | Silent (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- PCDH15 | c.1596T>A p.T532= | Silent (SNP) | VAF 34/448 reads (8%) | called by muse, mutect2
- SIRPD | c.441C>T p.P147= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- TRIB3 | c.834C>T p.Y278= | Silent (SNP) | VAF 56/323 reads (17%) | catalogued as rs375469008, COSV53930327; called by muse, mutect2, varscan2
- ARHGAP45 | c.1186-80G>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
- GNB2 | c.-33C>T | 5'UTR (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- HAGHL | c.*325C>G | 3'UTR (SNP) | VAF 19/374 reads (5%) | called by muse, mutect2
- PRKDC | c.11651+13C>G | Intron (SNP) | VAF 53/301 reads (18%) | called by muse, mutect2, varscan2
- RCC1 | c.-327A>C | 5'UTR (SNP) | VAF 22/470 reads (5%) | called by muse, mutect2
- REN | c.*21G>A | 3'UTR (SNP) | VAF 86/476 reads (18%) | called by muse, mutect2, varscan2
